Gene-level copy-number profile of tumor specimen TCGA-IG-A97H-01A from TCGA case TCGA-IG-A97H, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 36.0 years (13,166 days).
Specimen TCGA-IG-A97H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.e90354b4-4f6d-43b6-a78e-0de06f6d154b.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A97H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 389 have no estimate.
https://portal.gdc.cancer.gov/files/2ec492cc-699a-45e9-bb42-d28b68359053

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 3,384; copy number 1: 27,065; copy number 2: 25,244; copy number 3: 3,627; copy number 4: 861; copy number 5: 25; copy number 6: 28.

Homozygous deletions (total copy number 0; autosomes only): 1,004 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–197,341, 4 genes: LINC01986, AC066595.1, CHL1-AS2, AC066595.2.
- chr5:142,770,377–143,229,011, 3 genes (within-gene range 0–1): ARHGAP26, ARHGAP26-AS1, AC008533.1.
- chr6:116,100,851–116,254,075, 5 genes (within-gene range 0–1): NT5DC1, COL10A1, NIP7P3, AL050331.2, TSPYL4.
- chr6:116,258,493–116,279,930, 2 genes: AL050331.1, TSPYL1.
- chr10:34,109,560–34,815,325, 1 gene (within-gene range 0–1): PARD3.
- chr10:34,488,583–34,676,041, 3 genes: ELOBP4, RPL37P18, RPS12P16.
- chr14:25,916,015–25,998,805, 1 gene: AL132633.1.
- chr15:91,853,708–92,172,435, 1 gene (within-gene range 0–1): SLCO3A1.
- chr17:26,981,694–27,626,438, 20 genes (within-gene range 0–1): AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1.
- chr17:60,677,453–61,392,838, 1 gene (within-gene range 0–1): BCAS3.
- chr17:60,899,891–61,135,969, 5 genes: RN7SL448P, AC005884.1, AC005884.2, RPL23AP74, AC005856.1.
- chr18:7,566,782–11,885,685, 96 genes (within-gene range 0–2) (broad region; genes not listed).
- chr18:11,882,622–14,252,140, 86 genes (within-gene range 0–2) (broad region; genes not listed).
- chr18:24,534,551–80,247,514, 776 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,540 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:56,538,452–56,538,911, 1 gene, copy number 3: RPL21P23.
- chr2:102,619,553–102,736,888, 2 genes, copy number 3 (within-gene range 2–3): SLC9A2, MFSD9.
- chr2:156,033,247–156,034,080, 1 gene, copy number 3: HEBP2P1.
- chr3:93,843,764–194,832,592, 1,674 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr3:195,274,745–195,443,044, 1 gene, copy number 4 (within-gene range 2–4): ACAP2.
- chr3:195,349,664–198,222,513, 116 genes, copy number 4 (broad region; genes not listed).
- chr5:58,198–36,876,700, 566 genes, copy number 3–4 (broad region; genes not listed).
- chr5:36,885,206–36,886,497, 1 gene, copy number 3: KRT18P31.
- chr5:37,106,228–37,249,421, 1 gene, copy number 3 (within-gene range 1–3): CPLANE1.
- chr5:37,209,364–38,845,829, 33 genes, copy number 3: OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2.
- chr6:49,430,360–56,394,094, 119 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr6:68,040,290–71,458,874, 44 genes, copy number 3–5: AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626.
- chr6:73,209,746–73,263,196, 1 gene, copy number 3 (within-gene range 2–3): AL365232.1.
- chr6:73,241,314–73,828,316, 24 genes, copy number 3–5 (within-gene range 2–5): KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109.
- chr6:74,069,451–74,690,727, 1 gene, copy number 4 (within-gene range 2–4): AL357507.1.
- chr6:74,530,248–74,850,484, 4 genes, copy number 4: AL356277.3, AL356277.1, AL356277.2, AL356473.1.
- chr7:70,972–32,428,131, 563 genes, copy number 3–4 (within-gene range 1–6) (broad region; genes not listed).
- chr7:98,214,624–98,479,225, 7 genes, copy number 3 (within-gene range 2–3): TECPR1, BRI3, BAIAP2L1, AC093799.1, RPS3AP26, PPIAP82, AC074121.1.
- chr7:110,590,082–110,592,204, 1 gene, copy number 4: AC073326.2.
- chr7:110,724,159–110,725,825, 1 gene, copy number 4: AC073326.1.
- chr7:111,726,110–124,765,792, 171 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr7:125,033,453–125,035,301, 1 gene, copy number 3: EEF1GP1.
- chr7:128,862,042–128,910,719, 1 gene, copy number 3 (within-gene range 1–3): KCP.
- chr7:128,912,732–130,506,465, 55 genes, copy number 3–6: AC025594.1, IRF5, AC025594.2, TNPO3, RN7SL306P, ODCP, TPI1P2, AC018639.1, AC011005.2, AC011005.3, CYCSP20, AC011005.1, TSPAN33, RNY1P11, SMO, AC011005.4, AHCYL2, AC009244.1, CDC26P1, STRIP2, SNRPGP3, RNU1-72P, SMKR1, AC078846.1, NRF1, RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335.
- chr7:130,507,660–130,508,282, 1 gene, copy number 6: AC007938.3.
- chr11:27,330,827–27,722,058, 11 genes, copy number 3: CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF.
- chr12:66,767–563,509, 14 genes, copy number 3 (within-gene range 2–3): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3.
- chr13:55,062,945–114,337,626, 667 genes, copy number 3 (within-gene range 1–5) (broad region; genes not listed).
- chr18:47,390–2,049,510, 46 genes, copy number 3–6: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1.
- chr18:1,927,727–4,455,307, 51 genes, copy number 3–4 (within-gene range 1–4): AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5.
- chr18:23,598,926–24,544,154, 28 genes, copy number 3: ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1.
- chr20:53,453,058–53,575,863, 3 genes, copy number 3: AL354993.2, Y_RNA, AL157838.1.
- chr21:35,713,139–41,357,727, 126 genes, copy number 3 (within-gene range 2–5) (broad region; genes not listed).
- chr21:41,420,304–46,665,124, 204 genes, copy number 3–6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 27,043. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
